FM case AD919 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/c069f643-c234-43a8-8a52-ea1a41a79eae

Female, 38.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the cervix uteri. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
